Somatic mutation profile of tumor specimen 0DRXEI from CCDI case PBCGLY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Paraganglioma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 16.8 years (6,148 days).
Specimen 0DRXEI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2c2896e-b80d-4552-a7a8-9d67b17ce4c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRXEO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d0ed578-c244-4385-9299-5350cf9fdf58

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 3, 5'UTR 2, Nonsense Mutation 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HYDIN | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 57/523 reads (11%) | catalogued as rs867513811; called by muse, mutect2, varscan2
- RAB34 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 28/290 reads (10%) | catalogued as rs139219728; called by muse, mutect2, varscan2
- TYSND1 | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs867292004; called by muse, mutect2, varscan2
- ZNF714 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 125/827 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as rs372934750; called by muse, mutect2, varscan2
- CUBN | c.5549-2A>G p.X1850_splice | Splice Site (SNP) | VAF 21/320 reads (7%) | called by muse, mutect2
- DNAL1 | c.219G>C p.R73S | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.267); called by mutect2, varscan2
- ASTN1 | c.2682A>G p.P894= | Silent (SNP) | VAF 82/635 reads (13%) | called by muse, mutect2, varscan2
- CCDC85A | c.936G>C p.G312= | Silent (SNP) | VAF 24/282 reads (9%) | catalogued as COSV68147129; called by muse, mutect2
- HSD3B2 | c.597C>T p.A199= | Silent (SNP) | VAF 13/158 reads (8%) | called by muse, mutect2
- RBM34 | c.585A>T p.T195= | Silent (SNP) | VAF 59/482 reads (12%) | called by muse, mutect2, varscan2
- CFLAR | c.606+1026T>A | Intron (SNP) | VAF 17/488 reads (3%) | called by muse, mutect2
- DNAI4 | c.-15G>A | 5'UTR (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- IZUMO4 | c.-4G>T | 5'UTR (SNP) | VAF 3/28 reads (11%) | called by muse, varscan2
